MMRF case MMRF_2531 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9046fcfb-0e05-48fc-a311-d6ef2a422ae1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 546 days (1.5 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.5 years (25,765 days); ISS stage: III; Days to last known disease status: 546 days (1.5 years); Days to last follow up: 546 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 85 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 413 days (1.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 423 days (1.2 years); Days to treatment end: 480 days (1.3 years).
   Treatment given: Therapeutic agents: Daratumumab + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 484 days (1.3 years); Days to treatment end: 546 days (1.5 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 484 days (1.3 years); Days to treatment end: 505 days (1.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 546.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 6.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2539 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 2.75 g/L; Immunoglobulin A 66.7 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 9.23 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 8.6 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 27 g/L; Total Protein 11.4 g/dL; Glucose 7.65 mmol/L.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 4.64 g/L; Immunoglobulin A 1.09 g/L; Immunoglobulin M 0.231 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 5.94 mmol/L.
- Day 151 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 3.22 g/L; Immunoglobulin M 0.385 g/L; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 370 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 7.8 g/dL; Glucose 7.7 mmol/L.
- Day 221 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 5.78 mmol/L.
- Day 360 (ECOG 0): Hemoglobin 7.25 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.22 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 5.34 mmol/L.
- Day 449 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 937 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 3 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 4.8 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.82 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 548 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 2.15 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 505: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 797 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 3 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 4.72 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 1.3 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 10 ×10⁹/L; Creatinine 490 µmol/L; Blood Urea Nitrogen 31.8 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day 1: Weight: 126 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (5 samples)
- Sample MMRF_2531_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2531_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_2531_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_2531_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 449 days (1.2 years).
- Sample MMRF_2531_2_PB_CD138pos: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Days to sample procurement: 449 days (1.2 years).
